Somatic mutation profile of tumor specimen 0DT4J7 from CCDI case PBCJFM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Dysembryoplastic neuroepithelial tumor; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 4.9 years (1,800 days).
Specimen 0DT4J7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a28f03e5-a1fd-47d9-b326-92be74399e7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT4I8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8988275-e5b4-4e8d-b4d1-71df49611033

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, In Frame Del 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs145387010, CM094353; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HIF3A | c.499C>T p.R167C (on ENST00000377670 / NM_152795.4; = p.R98C on NM_022462.4) | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371476587; called by muse, varscan2
- IGSF11 | c.914C>T p.S305F (on ENST00000393775 / NM_001015887.3; = p.S304F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/516 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as rs745602460; called by muse, mutect2, varscan2
- TSHZ2 | c.2101G>A p.V701I | Missense Mutation (SNP) | VAF 145/343 reads (42%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.979); catalogued as rs755119289, COSV61591252; called by muse, mutect2, varscan2
- RERE | c.2820_2825del p.A941_P942del | In Frame Del (DEL) | VAF 53/140 reads (38%) | called by mutect2, pindel, varscan2
- HNRNPCL1 | c.75T>A p.T25= | Silent (SNP) | VAF 58/126 reads (46%) | catalogued as COSV58611059; called by mutect2, varscan2
- RGS12 | c.3412-70T>C | Intron (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
